Somatic mutation profile of tumor specimen TCGA-FD-A3N6-01A (aliquot TCGA-FD-A3N6-01A-11D-A21A-08) from TCGA case TCGA-FD-A3N6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 43.1 years (15,758 days).
Specimen TCGA-FD-A3N6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ea6ca74-9a05-4ae0-821a-6db042bf754d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3N6-10A (Blood Derived Normal), aliquot TCGA-FD-A3N6-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c796752c-47f3-40fc-a19f-bce6de437b04

The open-access MAF lists 133 somatic variants for this specimen: 100 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 29, Nonsense Mutation 6, In Frame Del 2, 3'UTR 2, 5'Flank 1, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD3 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs192857485, COSV56678599; called by muse, mutect2, varscan2
- ACADS | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54370327; called by muse, mutect2, varscan2
- ADGRB2 | c.4339C>T p.R1447C | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs768509560, COSV57079030; called by muse, mutect2, varscan2
- ALDOB | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs778058461, COSV66398673; called by muse, mutect2, varscan2
- ANO4 | c.2471A>C p.N824T (on ENST00000392977 / NM_001286615.2; = p.N789T on NM_178826.4) | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV54613675; called by muse, mutect2, varscan2
- ATAD3B | c.588G>C p.Q196H (on ENST00000308647; = p.Q302H on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs781172015, COSV58023361; called by muse, mutect2, varscan2
- ATM | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs587779830, COSV53741732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP4B | c.16_18del p.E6del | In Frame Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs781651629; called by mutect2, pindel, varscan2
- ATP7A | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782603364, COSV58454039; called by muse, mutect2, varscan2
- BLM | c.1958A>T p.K653M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV61927498; called by muse, mutect2, varscan2
- CACNA1B | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53149292; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 83/262 reads (32%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CCDC85A | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV68155638; called by muse, mutect2, varscan2
- CELF1 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 81/177 reads (46%) | catalogued as COSV60116656; called by muse, mutect2, varscan2
- CEP152 | c.1687C>A p.L563M | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV57865037; called by muse, mutect2, varscan2
- CHST8 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52857465, COSV52863338; called by muse, mutect2, varscan2
- COL7A1 | c.8054G>A p.R2685Q | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886058630, COSV56477277; called by muse, mutect2
- CS | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57524609; called by muse, mutect2, varscan2
- CSMD2 | c.6004G>A p.V2002M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs568684319, COSV53964259; called by muse, mutect2, varscan2
- DENND3 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs544008138; called by mutect2, varscan2
- DMBX1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749749952, COSV63602627; called by muse, mutect2, varscan2
- DNAH1 | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs768977175, COSV70236423; called by muse, mutect2, varscan2
- DNAJC5G | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56080680, COSV56081314; called by muse, mutect2, varscan2
- EFNB1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370690590, COSV52662805; called by muse, mutect2, varscan2
- EIF4G1 | c.3452G>A p.G1151D (on ENST00000346169 / NM_198241.3; = p.G956D on NM_004953.5) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as rs1285898791, COSV59993933; called by muse, mutect2, varscan2
- ENTPD8 | c.1363G>A p.D455N (on ENST00000371506 / NM_001033113.2; = p.D418N on NM_198585.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs746981536, COSV58163784; called by muse, mutect2, varscan2
- ERBB4 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216559792, COSV53501739, COSV53588880; called by muse, mutect2, varscan2
- EWSR1 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1024220000, COSV58427795; called by muse, varscan2
- FBP1 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs568708589, COSV64690091; called by muse, mutect2, varscan2
- FRMD7 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53749032; called by muse, mutect2, varscan2
- FSCB | c.85C>A p.H29N | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs1289668049, COSV61219569; called by muse, mutect2, varscan2
- GABRG3 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV61510850, COSV61526145; called by muse, mutect2, varscan2
- GCN1 | c.5212G>C p.E1738Q | Missense Mutation (SNP) | VAF 111/408 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV56114947; called by muse, mutect2, varscan2
- GLI4 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as rs147593320, COSV60682672; called by muse, mutect2, varscan2
- GLYATL1 | c.279G>T p.E93D (on ENST00000317391 / NM_001354699.1; = p.E124D on NM_080661.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.845); catalogued as COSV55611493; called by muse, mutect2, varscan2
- GPR6 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1307308785, COSV51572066; called by muse, mutect2, varscan2
- GRIA1 | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53624918; called by muse, mutect2, varscan2
- HCN1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1348079874, COSV57514141; called by muse, mutect2, varscan2
- HIVEP2 | c.5387G>A p.R1796Q | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750329426, COSV50065342; called by muse, mutect2, varscan2
- ITGA2B | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261397461, CM066102, COSV52235220; called by muse, mutect2, varscan2
- ITIH5 | c.884A>T p.N295I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53674027; called by muse, mutect2
- KLHL6 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs1405916127, COSV58068756; called by muse, mutect2, varscan2
- KMT2C | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 15/23 reads (65%) | catalogued as COSV51470450; called by muse, mutect2, varscan2
- KMT2D | c.4542C>A p.Y1514* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | catalogued as COSV56419593; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs755666456, COSV51722872, COSV51727485; called by muse, mutect2
- MCM7 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as rs762150483, COSV57999031; called by muse, mutect2, varscan2
- MGAT1 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 49/127 reads (39%) | PolyPhen probably damaging (0.999); catalogued as rs973289735, COSV57135490; called by muse, mutect2, varscan2
- MIDEAS | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1385871883, COSV54094062; called by muse, mutect2
- MMP12 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58261631; called by muse, mutect2, varscan2
- MRPS14 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs776927395, COSV62880724; called by muse, mutect2, varscan2
- MTUS2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV70922572; called by muse, mutect2
- MUC5B | c.12919A>G p.T4307A | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs756788272, COSV71595667; called by mutect2, varscan2
- NAT10 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs552744350, COSV57666326; called by muse, varscan2
- NEIL3 | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV52813302, COSV52813765; called by muse, mutect2, varscan2
- NEUROD4 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV54474189; called by muse, mutect2, varscan2
- NOMO2 | c.2160G>C p.E720D | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV57918400; called by muse, varscan2
- NOP14 | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV58627821; called by muse, mutect2, varscan2
- NPAS3 | c.527A>G p.E176G (on ENST00000356141 / NM_001164749.2; = p.E144G on NM_022123.3) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58113009; called by muse, mutect2, varscan2
- NTRK3 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1205263292, COSV58114623, COSV58142385; called by muse, mutect2, varscan2
- PARD3B | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774201389, COSV62507843; called by muse, mutect2, varscan2
- PCDHGA6 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.124); catalogued as COSV54010962; called by muse, mutect2
- PCNX2 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV50897032; called by muse, mutect2, varscan2
- PHF14 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1331607804, COSV68855683; called by muse, mutect2
- PIP5K1C | c.1360C>G p.P454A | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58956019; called by muse, mutect2
- PLEKHA4 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54366348; called by muse, mutect2, varscan2
- POU4F2 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55584588, COSV55586816; called by muse, mutect2, varscan2
- PRDM5 | c.1582A>C p.K528Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.997); catalogued as COSV53367930; called by muse, mutect2, varscan2
- PTPRM | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV59882296; called by muse, mutect2, varscan2
- PTPRT | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV62021802; called by muse, mutect2
- RABGAP1L | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52329806; called by muse, mutect2, varscan2
- RAC3 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV60712965; called by muse, mutect2, varscan2
- RGS20 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 85/487 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.1); catalogued as COSV52022476; called by muse, mutect2, varscan2
- RPL31 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV51822805, COSV51823150; called by muse, mutect2, varscan2
- RYR3 | c.10736A>T p.Y3579F (on ENST00000389232; = p.Y3580F on NM_001036.6) | Missense Mutation (SNP) | VAF 227/588 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV66808846; called by muse, mutect2, varscan2
- SAP18 | c.454C>T p.P152S (on ENST00000607003; = p.P171S on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV66822972; called by muse, mutect2, varscan2
- SEPSECS | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57207688; called by muse, mutect2, varscan2
- SEPTIN6 | c.432T>G p.H144Q | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59717659; called by muse, mutect2, varscan2
- SLC25A43 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54219137; called by muse, mutect2, varscan2
- SMPD1 | c.508T>G p.W170G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54970786; called by muse, mutect2, varscan2
- SUFU | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs1283509771, COSV64016031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANGO2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs760638813, COSV59292708; called by muse, mutect2, varscan2
- TMTC4 | c.1774C>T p.R592C (on ENST00000376234 / NM_001350577.2; = p.R611C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1430665035, COSV60891405; called by muse, mutect2, varscan2
- TRAF7 | c.903G>T p.M301I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as COSV58218360; called by muse, mutect2
- TSPOAP1 | c.2713G>A p.G905S | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs547251993, COSV52106774; called by muse, mutect2, varscan2
- TUB | c.193G>A p.E65K (on ENST00000299506 / NM_177972.3; = p.E120K on NM_003320.4) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1236629301, COSV100210155, COSV55107341; called by muse, mutect2, varscan2
- UBR4 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779737220, COSV64399484; called by muse, mutect2, varscan2
- UGT1A1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.509); catalogued as rs144978321; called by muse, mutect2, varscan2
- UNC5C | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV71658461; called by muse, mutect2, varscan2
- VWF | c.2792G>C p.G931A | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV54634753; called by muse, mutect2, varscan2
- ZDHHC7 | c.620-1G>C p.X207_splice | Splice Site (SNP) | VAF 44/114 reads (39%) | catalogued as COSV58214080; called by muse, mutect2, varscan2
- ZNF721 | c.1978G>A p.E660K (on ENST00000338977; = p.E672K on NM_133474.4) | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV59097283; called by muse, mutect2, varscan2
- ZNF831 | c.4400C>T p.S1467L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64044224, COSV64045380; called by muse, mutect2, varscan2
- ZNF91 | c.2780C>A p.T927K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.111); catalogued as COSV56093291; called by muse, mutect2, varscan2
- ZSWIM5 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62737085; called by muse, mutect2, varscan2
- ADGRE2 | c.1462G>A p.G488S | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CA9 | c.304T>G p.S102A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2
- CCDC120 | c.1032del p.S345Pfs*8 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- UROS | c.234_236del p.N78del | In Frame Del (DEL) | VAF 28/71 reads (39%) | called by mutect2, pindel, varscan2
- ZBED8 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- ABCB4 | c.3831C>T p.V1277= (on ENST00000265723 / NM_018849.3; = p.V1270= on NM_000443.4) | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV55941879; called by muse, mutect2, varscan2
- ATP11A | c.2745G>A p.A915= | Silent (SNP) | VAF 119/282 reads (42%) | catalogued as rs200313549; called by muse, mutect2, varscan2
- BCAR1 | c.627G>A p.P209= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as rs759346688, COSV50804915; called by muse, mutect2, varscan2
- CDH5 | c.987C>T p.Y329= | Silent (SNP) | VAF 102/259 reads (39%) | catalogued as COSV58520152; called by muse, mutect2, varscan2
- CFTR | c.3447C>A p.S1149= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV50104031; called by muse, mutect2, varscan2
- DIMT1 | c.750C>G p.L250= | Silent (SNP) | VAF 46/171 reads (27%) | catalogued as COSV52235001; called by muse, mutect2
- DSC2 | c.2589A>G p.G863= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV51869527; called by muse, mutect2, varscan2
- EBF2 | c.99C>T p.V33= | Silent (SNP) | VAF 95/261 reads (36%) | catalogued as rs1342780865, COSV68780625; called by muse, mutect2, varscan2
- EQTN | c.540C>A p.I180= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV101192494; called by muse, mutect2
- FAM234A | c.1014C>T p.A338= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as rs768915747, COSV51454102; called by muse, mutect2, varscan2
- GPR45 | c.819C>T p.F273= | Silent (SNP) | VAF 108/280 reads (39%) | catalogued as COSV51523483; called by muse, mutect2, varscan2
- HOXB3 | c.684C>T p.S228= | Silent (SNP) | VAF 116/262 reads (44%) | catalogued as COSV57485793; called by muse, mutect2, varscan2
- HRH2 | c.1041G>T p.G347= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as COSV51576367; called by muse, mutect2, varscan2
- IQGAP1 | c.1284C>G p.L428= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV51591445; called by muse, mutect2, varscan2
- MC2R | c.721T>C p.L241= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV59620511; called by muse, mutect2, varscan2
- MEIS3 | c.237T>C p.A79= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1360011178; called by muse, mutect2
- MUC16 | c.16653C>T p.L5551= | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as rs1242721894, COSV67455698, COSV67494865; called by muse, mutect2, varscan2
- MUC17 | c.5448C>T p.S1816= | Silent (SNP) | VAF 146/381 reads (38%) | catalogued as rs1471192307, COSV60303739; called by muse, mutect2, varscan2
- NDUFS2 | c.786G>A p.L262= | Silent (SNP) | VAF 11/196 reads (6%) | catalogued as COSV57156153; called by muse, mutect2
- NOD2 | c.1323G>A p.E441= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs1224862712, COSV56054933; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPAS3 | c.1494C>T p.P498= (on ENST00000356141 / NM_001164749.2; = p.P466= on NM_022123.3) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs151099881; called by muse, varscan2
- NUP160 | c.1929G>A p.L643= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV65856125; called by muse, mutect2, varscan2
- OFD1 | c.2373G>A p.P791= | Silent (SNP) | VAF 71/146 reads (49%) | catalogued as rs369277849, COSV60799071; called by muse, mutect2, varscan2
- OSCP1 | c.405C>T p.F135= (on ENST00000356637 / NM_001330493.1; = p.F125= on NM_145047.5) | Silent (SNP) | VAF 87/203 reads (43%) | catalogued as COSV52488299; called by muse, mutect2, varscan2
- POLQ | c.7167C>T p.I2389= | Silent (SNP) | VAF 102/246 reads (41%) | catalogued as COSV51761603; called by muse, mutect2, varscan2
- PRAMEF15 | c.252C>G p.L84= | Silent (SNP) | VAF 34/116 reads (29%) | called by muse, varscan2
- SCN3A | c.2934C>G p.L978= | Silent (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- SMYD5 | c.417C>T p.P139= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV50265760; called by muse, mutect2, varscan2
- ZNF70 | c.699C>T p.F233= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV59533864; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918831 ins A | 5'Flank (INS) | VAF 10/34 reads (29%) | catalogued as rs1359426404; called by mutect2, pindel, varscan2
- CYP2A13 | c.*2C>A | 3'UTR (SNP) | VAF 45/116 reads (39%) | catalogued as rs765333088, COSV100386895, COSV100386943; called by muse, mutect2, varscan2
- SLC48A1 | c.*150G>A | 3'UTR (SNP) | VAF 20/81 reads (25%) | catalogued as rs781741715, COSV99316651; called by muse, mutect2, varscan2
- TUBB7P | n.1288G>T | RNA (SNP) | VAF 112/295 reads (38%) | called by muse, mutect2, varscan2
